Somatic mutation profile of tumor specimen TARGET-10-PAPCSZ-09A (aliquot TARGET-10-PAPCSZ-09A-01D) from TARGET case TARGET-10-PAPCSZ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.0 years (3,637 days).
Specimen TARGET-10-PAPCSZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec4d0986-0c34-4938-adab-ae0114641dab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPCSZ-10A (Blood Derived Normal), aliquot TARGET-10-PAPCSZ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e050337-50a6-47ca-932a-267d06b06a7f

The open-access MAF lists 70 somatic variants for this specimen: 48 protein-altering or splice-affecting, 15 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 15, Frame Shift Ins 4, 3'UTR 4, Nonsense Mutation 3, Splice Site 1, 5'UTR 1, 5'Flank 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC244258.1 | n.776G>A | Splice Region (SNP) | VAF 22/44 reads (50%) | catalogued as rs748983475; called by muse, varscan2
- ADAMTS6 | c.1781G>A p.G594E | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66863436; called by muse, mutect2, varscan2
- ADGRG4 | c.6188C>A p.T2063N | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as COSV54951068; called by muse, mutect2
- CARD11 | c.1156C>T p.R386* | Nonsense Mutation (SNP) | VAF 24/55 reads (44%) | catalogued as rs1252273985, COSV67798056, COSV67801999; called by muse, mutect2, varscan2
- CRTAP | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 122/225 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs145644749; called by muse, mutect2, varscan2
- DCC | c.2407G>A p.G803R | Missense Mutation (SNP) | VAF 108/241 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs797044550, CM145928, COSV59121170; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DMAP1 | c.203C>A p.A68E | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.298); catalogued as COSV60000565; called by muse, mutect2
- DNAH9 | c.5431C>T p.R1811C | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746428454, COSV52349131; called by muse, mutect2, varscan2
- FGFR2 | c.2383G>A p.D795N | Missense Mutation (SNP) | VAF 94/224 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1024846807, COSV60646323, COSV60664365; called by muse, varscan2
- FSIP2 | c.11320C>T p.P3774S | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV58080568; called by muse, mutect2, varscan2
- GABRR2 | c.1291G>A p.G431S | Missense Mutation (SNP) | VAF 67/165 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as COSV101298876; called by muse, mutect2, varscan2
- HCN4 | c.1043C>T p.S348F | Missense Mutation (SNP) | VAF 134/278 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56083764; called by muse, mutect2, varscan2
- ITGAV | c.2062C>T p.R688* | Nonsense Mutation (SNP) | VAF 27/71 reads (38%) | catalogued as rs1249598046; called by muse, mutect2, varscan2
- KIF5A | c.967C>T p.R323W | Missense Mutation (SNP) | VAF 80/175 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1012819766, CM152455, COSV54059248; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KRAS | c.53C>A p.A18D | Missense Mutation (SNP) | VAF 55/155 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55561078, COSV55580549, COSV55715402; called by muse, mutect2, varscan2
- KRTAP26-1 | c.526C>T p.L176F | Missense Mutation (SNP) | VAF 35/270 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.099); catalogued as COSV62129442; called by muse, mutect2, varscan2
- LILRB4 | c.25C>A p.L9I | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.007); catalogued as COSV54403327; called by muse, mutect2
- MYO7A | c.3094G>A p.E1032K | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.988); catalogued as rs1209629914, COSV68684387; called by muse, mutect2, varscan2
- MYO9A | c.6718G>T p.V2240L | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.133); catalogued as rs1181373420; called by muse, mutect2
- NACA2 | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 117/280 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs767833660, COSV71713104; called by muse, mutect2, varscan2
- NEB | c.3424G>A p.D1142N | Missense Mutation (SNP) | VAF 80/176 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747102490, COSV50900549, COSV51370440; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POMGNT2 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.606); catalogued as COSV60952843; called by muse, mutect2, varscan2
- RYR1 | c.3865C>T p.R1289W | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377185497, COSV62090900, COSV62101258; called by muse, mutect2, varscan2
- SPHKAP | c.2719G>A p.D907N | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.042); catalogued as rs1182443651, COSV60873942; called by muse, mutect2, varscan2
- TMEM41B | c.694G>T p.G232C | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs1234200679; called by muse, mutect2
- TMTC1 | c.2602C>T p.R868C (on ENST00000539277 / NM_001193451.2; = p.R760C on NM_175861.3) | Missense Mutation (SNP) | VAF 120/246 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55478768; called by muse, mutect2, varscan2
- UNC80 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.025); catalogued as COSV55886886; called by muse, mutect2, varscan2
- WWOX | c.8C>A p.A3E | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1241157001; called by muse, mutect2
- ARHGAP29 | c.177A>C p.L59F | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CBX5 | c.130_131insCCCCCGGC p.F44Sfs*22 | Frame Shift Ins (INS) | VAF 12/36 reads (33%) | called by mutect2, pindel*
- CLTCL1 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 56/114 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- DSC2 | c.1390G>A p.D464N | Missense Mutation (SNP) | VAF 55/173 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- FILIP1 | c.3514G>A p.V1172I | Missense Mutation (SNP) | VAF 74/160 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GOLGA3 | c.2464G>T p.G822C | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); called by muse, mutect2
- GPX5 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0.087); called by muse, mutect2
- JAK1 | c.1871_1872insTGGAA p.L624Ffs*20 | Frame Shift Ins (INS) | VAF 56/146 reads (38%) | called by mutect2, pindel*, varscan2*
- LRP1B | c.9020G>A p.C3007Y | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NEMF | c.2521G>A p.G841R | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NEXMIF | c.1583G>A p.R528K | Missense Mutation (SNP) | VAF 29/33 reads (88%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, varscan2
- PLOD3 | c.2116G>A p.G706S | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLS1 | c.1372-1G>A p.X458_splice | Splice Site (SNP) | VAF 24/40 reads (60%) | called by muse, mutect2, varscan2
- RIPOR1 | c.638_641dup p.K214Nfs*17 (on ENST00000379312 / NM_001193522.2; = p.K210Nfs*17 on NM_024519.4) | Frame Shift Ins (INS) | VAF 24/64 reads (38%) | called by mutect2, varscan2
- SATB2 | c.1492G>A p.A498T | Missense Mutation (SNP) | VAF 112/241 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SH2B3 | c.968_969insCTTAA p.E324Lfs*51 | Frame Shift Ins (INS) | VAF 80/84 reads (95%) | called by mutect2, pindel, varscan2
- TBX21 | c.773T>C p.I258T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- TMTC1 | c.1273G>T p.V425L (on ENST00000539277 / NM_001193451.2; = p.V317L on NM_175861.3) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); called by muse, mutect2
- WDFY4 | c.6193C>A p.H2065N | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2
- ZNF217 | c.1932_1933insCAGCTGTAGAACCAAG p.A645Qfs*3 | Nonsense Mutation (INS) | VAF 27/86 reads (31%) | called by mutect2, varscan2
- COL3A1 | c.825G>A p.K275= | Silent (SNP) | VAF 62/160 reads (39%) | catalogued as rs754262933; called by muse, mutect2, varscan2
- DGKZ | c.93C>G p.P31= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs781738735; called by muse, mutect2, varscan2
- DOP1B | c.6735A>C p.P2245= | Silent (SNP) | VAF 63/484 reads (13%) | called by muse, mutect2, varscan2
- EFTUD2 | c.2142G>T p.L714= | Silent (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- EGFR | c.762C>T p.F254= | Silent (SNP) | VAF 57/125 reads (46%) | catalogued as COSV51858871; called by muse, mutect2, varscan2
- GLB1L3 | c.1047C>T p.F349= | Silent (SNP) | VAF 35/74 reads (47%) | catalogued as rs1191171531; called by muse, mutect2, varscan2
- IQGAP1 | c.2949C>T p.P983= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as rs777611381; called by muse, mutect2, varscan2
- KIF18B | c.1260C>T p.L420= (on ENST00000593135 / NM_001265577.2; = p.L432= on NM_001264573.2) | Silent (SNP) | VAF 14/23 reads (61%) | catalogued as rs267604913; called by muse, varscan2
- OR5AP2 | c.282G>A p.E94= | Silent (SNP) | VAF 52/113 reads (46%) | called by muse, mutect2, varscan2
- RGS7BP | c.717C>T p.P239= | Silent (SNP) | VAF 67/160 reads (42%) | catalogued as rs745775006, COSV61834767; called by muse, mutect2, varscan2
- SLC19A2 | c.156C>T p.F52= | Silent (SNP) | VAF 48/99 reads (48%) | catalogued as rs375301246; called by muse, mutect2, varscan2
- SMAD6 | c.1233C>T p.F411= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV99994210; called by muse, mutect2, varscan2
- TENM2 | c.2379T>G p.G793= (on ENST00000518659 / NM_001122679.2; = p.G561= on NM_001080428.3) | Silent (SNP) | VAF 37/80 reads (46%) | called by muse, mutect2, varscan2
- TTN | c.69909T>C p.H23303= (on ENST00000591111; = p.H15879= on NM_003319.4) | Silent (SNP) | VAF 37/90 reads (41%) | catalogued as rs1302451459; called by muse, mutect2, varscan2
- ZNF683 | c.1068G>A p.Q356= | Silent (SNP) | VAF 37/121 reads (31%) | catalogued as rs1171439363; called by muse, mutect2, varscan2
- CCDC110 | c.-36G>A | 5'UTR (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- DCP2 | chr5:112976789 C>T | 5'Flank (SNP) | VAF 38/73 reads (52%) | catalogued as rs777066357; called by muse, mutect2, varscan2
- MOCS1 | c.*942C>T | 3'UTR (SNP) | VAF 83/172 reads (48%) | called by muse, mutect2, varscan2
- SALL2 | c.*503C>T | 3'UTR (SNP) | VAF 32/71 reads (45%) | called by muse, mutect2, varscan2
- SMPX | c.*84G>A | 3'UTR (SNP) | VAF 33/34 reads (97%) | called by muse, mutect2, varscan2
- TGFBR3 | c.*2306G>T | 3'UTR (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- TNRC6C | c.4307-586C>A | Intron (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
